TCGA case TCGA-12-0670 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f7dd387f-eca9-4028-b296-2ca6d56d3bde

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 790 days (2.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 60.8 years (22,189 days); Year of diagnosis: 2001; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Chimeric Monoclonal Antibody 81C6; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 77 days; Treatment dose: 10 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Days to treatment start: 43 days; Days to treatment end: 77 days; Treatment dose: 80 mCi.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 77 days; Days to treatment end: 122 days; Treatment dose: 5,940 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 148 days; Days to treatment end: 183 days; Number of cycles: 1; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 183 days; Days to treatment end: 203 days; Number of cycles: 1; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 211 days; Days to treatment end: 288 days; Number of cycles: 2; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 327 days; Days to treatment end: 378 days (1.0 years); Treatment dose: 125 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 329 days; Days to treatment end: 378 days (1.0 years); Number of cycles: 1; Treatment dose: 125 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 407 days (1.1 years); Days to treatment end: 448 days (1.2 years); Treatment dose: 125 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 407 days (1.1 years); Days to treatment end: 448 days (1.2 years); Number of cycles: 1; Treatment dose: 125 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 448 days (1.2 years); Days to treatment end: 516 days (1.4 years); Treatment dose: 125 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 448 days (1.2 years); Days to treatment end: 516 days (1.4 years); Treatment dose: 200 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 448 days (1.2 years); Days to treatment end: 516 days (1.4 years); Number of cycles: 2; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 516 days (1.4 years); Days to treatment end: 576 days (1.6 years); Treatment dose: 125 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 516 days (1.4 years); Days to treatment end: 576 days (1.6 years); Number of cycles: 2; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 516 days (1.4 years); Days to treatment end: 576 days (1.6 years); Treatment dose: 200 mg; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 578 days (1.6 years); Days to treatment end: 601 days (1.6 years); Treatment dose: 125 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 578 days (1.6 years); Days to treatment end: 601 days (1.6 years); Number of cycles: 1; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 578 days (1.6 years); Days to treatment end: 601 days (1.6 years); Treatment dose: 200 mg; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 601 days (1.6 years); Days to treatment end: 722 days (2.0 years); Treatment dose: 125 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 601 days (1.6 years); Days to treatment end: 722 days (2.0 years); Treatment dose: 200 mg; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Celecoxib; Treatment intent type: Adjuvant; Days to treatment start: 722 days (2.0 years); Days to treatment end: 770 days (2.1 years); Treatment dose: 125 mg/m2; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 61.8 years (22,568 days); Days to diagnosis: 379 days (1.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 744 days (2.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 379 (post initial treatment): Progression or recurrence: Yes; Days to progression: 379 days (1.0 years).
- Karnofsky performance status: 100; Timepoint: Prior to Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Follow-up contact recording only the day: day 790.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0670-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-12-0670-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-12-0670-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-12-0670-01B-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-12-0670-01B-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-12-0670-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0670-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: CPT-11.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: MAB I131.
- Drug treatment 5: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 8: Pharmaceutical therapy drug name: Celebrex.
- Drug treatment 15: Pharmaceutical therapy drug name: ch81c6.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 790 days; disease-specific survival: event status not recorded, 790 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 379 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0670-01B-01D-0384-01): tumor purity 0.89, ploidy 2, whole-genome doublings 0.
